Gene-level copy-number profile of tumor specimen TCGA-09-2043-01A from TCGA case TCGA-09-2043, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 69.8 years (25,480 days).
Specimen TCGA-09-2043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.90a5754c-687f-4aeb-b600-b4dcc28c870c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-2043-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6208227c-0dc5-4af4-9d60-9107cb19b1eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,505; copy number 2: 29,786; copy number 3: 11,863; copy number 4: 4,398; copy number 5: 1,012; copy number 6: 857; copy number 7: 340; copy number 8: 17; copy number 9: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-2043-01A-01D-0704-01): tumor purity 0.88, ploidy 2.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,254 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,445,579–147,626,216, 4 genes, copy number 5 (within-gene range 3–5): OR13Z2P, OR13Z3P, BCL9, AC242628.1.
- chr2:42,826,322–54,383,742, 175 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–27,496,994, 426 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:18,892,096–20,415,754, 22 genes, copy number 5: HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1.
- chr7:66,628,881–67,362,950, 25 genes, copy number 5: KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2.
- chr7:124,822,386–159,233,377, 787 genes, copy number 5–6 (broad region; genes not listed).
- chr8:140,505,813–141,002,216, 10 genes, copy number 5 (within-gene range 4–5): AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr12:66,767–20,098,868, 583 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:40,554,161–41,072,415, 3 genes, copy number 5 (within-gene range 2–5): RNU6-713P, CNTN1, AC016144.1.
- chr21:28,743,208–37,019,662, 219 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,696. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
